Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A468, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A468-01A (Primary Tumor).

[page 1 of 3]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

COMMENT:

Additional sections of the mandible are received from the bone lab after decalcification and sectioning.

The section code is as follows:

Cassettes I17 and I18, cross sections of the mandible; cassette I19, mandibular margin, en face; cassette I20 and I21, right mandibular margin, en face.

ADDITIONAL DIAGNOSIS:

All sections of bony mandibular tissue are free of carcinoma.

*ICD-O-3
carcinoma, squamous cell, keratinizing, NOS
Site: lip, NOS C00.9 8071/3*

Entire report and diagnosis completed by:
Report released by:

hw 10/1/12

DIAGNOSIS

- (A) SUBMENTAL TRIANGLE:
METASTATIC SQUAMOUS CARCINOMA IN 1 (FOCAL 0.6 MM) OF 3 LYMPH NODES (1/3).
- (B) LEVEL IB LEFT NECK:
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 5 LYMPH NODES (1/5), EXTRANODAL EXTENSION OF TUMOR IS PRESENT.
- (C) LEVEL II LEFT NECK:
Eleven lymph nodes, no tumor present (0/11).
- (D) LEVEL III LEFT NECK:
Fifteen lymph nodes, no tumor present (0/15).
- (E) RIGHT MENTAL NERVE:
Segment of nerve, no tumor present.
- (F) LEFT INFERIOR ALVEOLAR NERVE:
Segment of nerve, no tumor present.
- (G) SUPERIOR LIP MARGIN:
No tumor present.
- (H) INFERIOR LIP MARGIN:
No tumor present.
- (I) MARGINAL MANDIBULECTOMY INCLUDING UPPER AND LOWER LIP:
DEEPLY INVASIVE KERATINIZED SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED IN SUBMUCOSA AND EXTENDING TO THE SKIN WITH PERINEURAL INVASION. Margins free of tumor.

[page 2 of 3]
DOB: _____
Physician: _____

Sex: M

Received: _____

Pathologist: _____
Case type: Surgical History

Accession: _____

- (J) TEETH:
Teeth and tooth fragments (gross examination only).

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) SUBMENTAL TRIANGLE - An irregular fragment of fibroadipose tissue (4.0 x 3.0 x 2.0 cm) containing multiple tan unremarkable lymph nodes. No salivary gland is identified. A single area of fibrosis is present. This measures 1.5 cm in greatest dimension.

SECTION CODE: A1, two lymph nodes; A2, three possible lymph nodes; A3, one lymph node; A4, multiple possible lymph nodes; A5, area of fibrosis.

(B) LEVEL IB LEFT NECK - A portion of salivary gland (4.0 x 4.0 x 3.0 cm) with attached fibroadipose tissue containing multiple lymph nodes ranging in size from 0.5 to 1.5 cm. The salivary gland parenchyma is unremarkable. The lymph nodes are ovoid and also unremarkable. No tumor is seen.

SECTION CODE: B1, representative section of salivary gland; B2-B3, one lymph node serially sectioned; B4, three lymph nodes. OT/ymb

(C) LEVEL II LEFT NECK - An irregular fragment of fibroadipose tissue (6.0 x 4.0 x 2.0 cm) containing multiple tan ovoid unremarkable lymph nodes ranging in size from 0.3 to 3.0 cm.

SECTION CODE: C1, four lymph nodes; C2, two possible lymph nodes; C3, two possible lymph nodes; C4, two possible lymph nodes; C5, one lymph node bisected; C6, one lymph node bisected; C7-C11, one entire lymph node; C12-C15, one entire lymph node.

(D) LEVEL III LEFT NECK - An irregular fragment of fibroadipose tissue with attached skeletal muscle (4.0 x 4.0 x 3.0 cm) containing multiple tan unremarkable lymph nodes ranging in size from 0.3 to 3.0 cm.

SECTION CODE: D1, D2, one lymph node, bisected; D3, two lymph nodes; D4, two possible lymph nodes; D5, three lymph nodes; D6, two possible lymph nodes; D7, four lymph nodes; D8, four possible lymph nodes.

(E) RIGHT MENTAL NERVE - One fragment of tan soft tissue measuring 0.3 cm in greatest dimension. Entirely submitted in E for frozen section.

*FS/DX: SEGMENT OF NERVE, NO TUMOR PRESENT.

(F) LEFT INFERIOR ALVEOLAR NERVE - A 0.3 x 0.2 x 0.2 cm soft tissue fragment, entirely submitted as FSF.

*FS.DX: SEGMENT OF NERVE, NO TUMOR PRESENT.

(G) SUPERIOR LIP MARGIN - A single flat piece of soft tissue (1.5 x 1.0 x 0.3 cm). One surface of the specimen is marked with blue ink. The specimen is submitted entirely for frozen section in a slide G.

*FS/DX: NO TUMOR PRESENT.

(H) INFERIOR LIP MARGIN - A single piece of fatty, tan-red soft tissue (2.0 x 1.5 x 0.2 cm). One surface of the specimen is marked with blue ink. The specimen is bisected and entirely submitted en face for frozen section.

[page 3 of 3]
DOB:
Physician.

Sex: M

Received:

Pathologist:

Accession:

Case type: Surgical History

*FS/DX: NO TUMOR PRESENT.

(I) MARGINAL MANDIBULECTOMY INCLUDING UPPER AND LOWER LIP - A partial mandibulectomy specimen (superior to inferior, 9.0 cm; medial to lateral, 7.5 cm; anterior to posterior, 2.5 cm) including the anterior portion of the anterior mandible (including the alveolar ridge) and mental portion. The inferior alveolar nerve is included with the mandible as well as skin on the anterior portion and oral mucosa on the posterior portion.

A purple, multinodular, and raised at the left corner of the mouth. Additional tumor nodules of varying size ranging from 0.3 to 0.6 cm in diameter are dispersed throughout the rest of the specimen. The skin margins are grossly free of tumor. One of the satellite tumor nodules is located 0.9 cm from the upper lip medial margin. An additional nodule is located 1.5 cm from the lower lip margin. Nodules are present on the oral mucosa, but the surface mucosa is intact, smooth, and glistening.

The anterior mandible is unremarkable. Tumor invades to within 0.2 cm of the bone. No tumor invasion of bone is grossly identified. No teeth are included with the specimen.

INK CODE: Blue-margins from area separately submitted by surgeon as specimens G and H. Black-soft tissue margins from remainder of specimen.

SECTION CODE: I1 and I2, left upper lip margin, perpendicular; I3, tumor left upper lip; I4 and I5, full thickness cross section including soft tissue margin of resection; I6 and I7, tumor from left upper lip; I8, cross section of skin and mucosa; I9 and I10, closest soft tissue margin from lateral specimen (perpendicular); I11-I13, tumor from left lower lip; I14, alveolar mucosal margin, en face; I15, I16, left lower lip margin, perpendicular: The tumor is transferred to the bone lab for further processing.

(J) TEETH - Multiple teeth and fragments of teeth, 5.5 x 5.0 x 3.0 cm in aggregate. The teeth include molars, pre-molars, and canine. Focally, the teeth show dental caries. No sections are taken.

SNOMED CODES

M-80703 M-80706 T-02120 T-03120 T-51300 T-C4200

9/9/12

Page 3 of 3

History Case Pathology Report
File under: Pathology

History Case Pathology

Source: NCI Genomic Data Commons file 52b0c565-6f20-4791-a6c3-3894e8079c6c (TCGA-CV-A468.2EF86B2F-6058-411A-A225-DF282C36A7BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).